Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A44K, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A44K-01A (Primary Tumor).

Procurement Date: Laterality: Tumor consists of trabeculae or papillae having an fine or broad fibrovascular stalk covered by a single to mutiple layers of cuboidal epithelial cells. Tumor invades in capsule or vessle or begnin tissue. The cells tend to maintain their polarity. Nulei are quite regular and contain finely dispersed chromatin, or intranuclear grooves. Tumor is invasion of inflammatory cells. Stroma is fibrous and hyaline.

Path Report:Thyroid Gland Tumor Checklist

Tumor type: Papillary carcinoma

Tumor size: 2 x 1.5 x 1.5 cm

Laterality: Left

Focality: Unifocal

Extrathyroidal extension: No

Markers and special stains: None

Additional comments: None

ICD-O3
carcinoma, papillary, thyroid
826013
Site: thyroid, NOS
8-31-12 C73.9
RO

Noted		☒
Reviewed (initials)	RMI	8/14/12

Source: NCI Genomic Data Commons file f5914aba-c165-409d-b76a-d9692cbb2848 (TCGA-E8-A44K.65882DB3-606B-4C8C-9B7B-67D996F982C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).